Somatic mutation profile of tumor specimen TCGA-ZG-A9ND-01A (aliquot TCGA-ZG-A9ND-01A-11D-A41K-08) from TCGA case TCGA-ZG-A9ND, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 55.9 years (20,428 days).
Specimen TCGA-ZG-A9ND-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e5ad8da0-5766-4fe5-ab5e-50880a31f3f1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZG-A9ND-10A (Blood Derived Normal), aliquot TCGA-ZG-A9ND-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ac9aafb5-49d3-425d-80f7-e9cecda2e4ad

The open-access MAF lists 27 somatic variants for this specimen: 23 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 17, Frame Shift Del 4, Silent 4, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SPOP | c.391T>G p.W131G | Missense Mutation (SNP) | VAF 57/158 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.491); catalogued as rs1057519968, COSV61652911, COSV61653817; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- APOL4 | c.454A>G p.I152V (on ENST00000352371 / NM_145660.2; = p.I149V on NM_030643.4) | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs773097290, COSV100274097; called by muse, mutect2
- CCDC85A | c.1394G>A p.R465Q | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs921834802, COSV68151614; called by muse, mutect2
- DCC | c.3692G>A p.R1231Q | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs895467720, COSV71428005; called by muse, mutect2, varscan2
- FAM47B | c.890C>T p.P297L | Missense Mutation (SNP) | VAF 43/58 reads (74%) | SIFT tolerated (0.7); PolyPhen benign (0.006); catalogued as rs370213556, COSV61453664; called by muse, mutect2, varscan2
- FBXO39 | c.1181G>A p.C394Y | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100386181; called by muse, mutect2, varscan2
- ITGA2 | c.1840C>T p.H614Y | Missense Mutation (SNP) | VAF 44/60 reads (73%) | SIFT tolerated (0.09); PolyPhen benign (0.212); catalogued as COSV99670609; called by muse, mutect2, varscan2
- ITIH6 | c.3419C>A p.T1140N | Missense Mutation (SNP) | VAF 28/31 reads (90%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV99513157; called by muse, mutect2, varscan2
- KLHL28 | c.1088C>A p.T363K | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as rs1368023859, COSV100753075; called by muse, mutect2, varscan2
- MARCHF4 | c.1187C>T p.P396L | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as COSV99814257; called by muse, mutect2, varscan2
- MSH6 | c.2838A>C p.E946D | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.02); catalogued as COSV99315695; called by muse, mutect2, varscan2
- PPP1R12B | c.2816G>C p.R939T | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as COSV99294779; called by muse, mutect2, varscan2
- TMBIM6 | c.233A>G p.H78R | Missense Mutation (SNP) | VAF 99/230 reads (43%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV99920674; called by muse, mutect2, varscan2
- TMEM268 | c.944C>G p.T315R | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.326); catalogued as COSV99938644; called by muse, mutect2, varscan2
- TRIM72 | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1370032300, COSV100265385; called by muse, mutect2
- TTF1 | c.2396dup p.Y799* | Nonsense Mutation (INS) | VAF 21/65 reads (32%) | catalogued as rs753268627; called by mutect2, pindel, varscan2
- USP47 | c.2042G>A p.G681E (on ENST00000399455 / NM_001372095.1; = p.G593E on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as COSV100359419; called by muse, mutect2, varscan2
- VCL | c.913G>T p.E305* | Nonsense Mutation (SNP) | VAF 27/72 reads (38%) | catalogued as COSV99280691; called by muse, mutect2, varscan2
- CR2 | c.1480del p.S494Lfs*8 | Frame Shift Del (DEL) | VAF 41/118 reads (35%) | called by mutect2, pindel, varscan2
- FER1L6 | c.2395_2399del p.G799* | Frame Shift Del (DEL) | VAF 13/78 reads (17%) | called by mutect2, pindel, varscan2
- MAP2K3 | c.731G>A p.G244D (on ENST00000342679 / NM_145109.3; = p.G215D on NM_002756.4) | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PIKFYVE | c.4926del p.P1643Lfs*9 | Frame Shift Del (DEL) | VAF 38/118 reads (32%) | called by mutect2, pindel, varscan2
- UBLCP1 | c.436del p.Y146Ifs*14 | Frame Shift Del (DEL) | VAF 15/40 reads (38%) | called by mutect2, varscan2
- BPNT2 | c.690T>C p.S230= | Silent (SNP) | VAF 30/120 reads (25%) | catalogued as COSV99388955; called by muse, mutect2, varscan2
- BRIX1 | c.750A>G p.G250= | Silent (SNP) | VAF 28/69 reads (41%) | catalogued as COSV100331342; called by muse, mutect2, varscan2
- ICE1 | c.2775A>G p.S925= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as rs1161395615, COSV99664429; called by muse, mutect2, varscan2
- SCAF11 | c.3924T>G p.S1308= | Silent (SNP) | VAF 32/89 reads (36%) | catalogued as COSV101014245; called by muse, mutect2, varscan2
